CCDI case PBCKRR — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/7c6995e5-0146-4ef2-a6a2-bf2a14ddd973

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Ependymoma, NOS: ICD-O-3 morphology code: 9391/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 2.8 years (1,016 days).

Biospecimens (3 samples)
- Sample 0DU9MH: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DU9MV: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DU9NC: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
